Somatic mutation profile of tumor specimen 0DQOF8 from CCDI case PBCFEZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.4 years (6,719 days).
Specimen 0DQOF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee3e149d-124f-4825-bb54-25276d1c6ff7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOEU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24bd02ab-d1a7-4d8b-9f53-41b812470218

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CERCAM | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs201729613; called by muse, varscan2
- INHBB | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs762062674; called by muse, varscan2
- ITIH2 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs926900984; called by muse, varscan2
- LRP2 | c.9595C>A p.P3199T | Missense Mutation (SNP) | VAF 148/416 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449419275, COSV55574307; called by muse, varscan2
- NF2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 182/276 reads (66%) | catalogued as CM023965, COSV58520193; called by muse, varscan2
- RYR2 | c.5602C>A p.L1868I | Missense Mutation (SNP) | VAF 130/394 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs768636940; called by muse, varscan2
- DLX3 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.593); called by muse, varscan2
- EDRF1 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 220/632 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, varscan2
- PCYT2 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, varscan2
- SLC2A14 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, varscan2
- C2CD3 | c.5121A>G p.Q1707= | Silent (SNP) | VAF 150/471 reads (32%) | catalogued as rs909010609; called by muse, varscan2
- FAM47A | c.825C>T p.D275= | Silent (SNP) | VAF 98/339 reads (29%) | catalogued as COSV60494645; called by muse, varscan2
- GDPD2 | c.309G>A p.L103= | Silent (SNP) | VAF 102/288 reads (35%) | called by muse, varscan2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, varscan2
